Surgical pathology report (de-identified scan), TCGA case TCGA-D3-A5GT, project TCGA-SKCM (Skin Cutaneous Melanoma), tissue source site MD Anderson, specimen TCGA-D3-A5GT-01A (Primary Tumor).

[page 1 of 2]
DIAGNOSIS

path *ICD-O-3*
Melanoma Malignant, superficial spreading
type 8743/3
Melanoma, malignant NOS 8720/3
Site: Skin of Arm C44.5
Q10 4/4/13

(A) RIGHT INGUINAL CONTENTS WITH EN BLOC WITH RIGHT MEDIAL GROIN, EXCISION:

MELANOMA, INVASIVE, SUPERFICIAL SPREADING TYPE
CLARK LEVEL, IV
BRESLOW THICKNESS, 10.0 MM
RADIAL (NON-TUMORIGENIC) GROWTH PHASE, PRESENT
VERTICAL (TUMORIGENIC) GROWTH PHASE, PRESENT
MITOTIC FIGURES/MM2, 14
ULCERATION, PRESENT (5MM)
REGRESSION, PRESENT, FOCAL
VASCULAR INVASION, PRESENT
MICROSCOPIC SATELLITOSIS, PRESENT
SURGICAL MARGINS: FREE OF MALIGNANCY
Skin and subcutis with healing surgical wound.
(Correlation with _____ is recommended)

MELANOMA, METASTATIC TO TWO OF TEN LYMPH NODES (2/10).

Tumor location: Subcapsular and intraparenchymal.

Largest tumor deposit size: 40.0 x 35.0 mm. (per gross exam)

Extracapsular extension: Present

(B) RIGHT ILIAC AND OBTURATOR CONTENTS, EXCISION:

MELANOMA, METASTATIC TO TWO OF SEVEN LYMPH NODES (2 / 7).

Largest tumor deposit size: 12.0 x 10.0 mm. (as measured on slide)

Extracapsular extension: Not identified

GROSS DESCRIPTION

(A) LABELED "RIGHT INGUINAL CONTENTS WITH EN BLOC CONTINUITY 2 CM MARGIN MELANOMA, RIGHT MEDIAL GROIN" – A surgeon oriented right groin dissection specimen that includes medial scrotal aspect with overall dimensions (21.0 x 9.5 x 4.1 cm). The hairy curved tan portion of skin includes the inguinal/groin contents and scrotal aspect along the medial aspect. The curved skin ellipse measures 21 cm in length and 6 cm in depth.

There is a skin mass that is dark red to black, measuring 2.2 x 2.0 x 1.7 cm which is located 1.5 cm from the superior margin, 1.5 cm from the medial scrotal skin margin and 2.0 cm from the inferior skin margin. There is pigmented dark brown flat area of lateral extension in an area, measuring 2 x 1 cm. The lab _____ tissue bank from this primary skin melanotic lesion will be submitted as well as a metastatic lymph node as the #2 source. There are multiple enlarged groin lymph nodes, the largest measures 4.0 x 3.5 cm and will be harvested. The margins are inked, serially sectioned, medial to lateral to reveal additional lymph nodes that range from 0.3 cm up to 3 cm, some have gross fatty replacement. All of the possible groin lymph nodes are submitted.

INK CODE: Blue – superior margin; yellow – inferior margin; red – inferior aspect of the medial skin melanotic lesion, not a true margin, for orientation purposes/inferior aspect of lesion.

SECTION CODE: A1, A2, en face skin, superior margin, ink side up; A3, A4, en face, medial skin margin, ink side up; A5, A6, en face, inferior skin margin, ink side up; A7, lateral skin apical tip, ink side up; A8-A15, primary skin lesion in consecutive order; A16, A17, deep margin, beneath primary skin lesion, ink side up; A18, A19, lymph node with metastatic melanoma and closest inked deep margin; A20, A21, largest lymph node with melanoma infiltrates (harvest site #2); A22, three possible intact lymph nodes; A23-A25, one possible bisected lymph node, each cassette; A26, A27, one possible bisected lymph node; A28, one possible bisected lymph node; A29-A31, one possible serially sectioned lymph node.

(B) RIGHT ILIAC AND OBTURATOR CONTENTS - Three pink-red irregular pieces of soft tissue aggregating 5.5 x 3.5 x 1.1 cm. There are multiple pink-red lymph nodes that range from 0.3 cm up to 5.0 cm in greatest length.

SECTION CODE: B1, B2, three possible intact lymph nodes, each cassette; B3, one possible bisected lymph node; B4-B7, one possible serially sectioned lymph node; B8-B12, one possible serially sectioned lymph node.

[page 2 of 2]
CLINICAL HISTORY

Melanoma

SNOMED CODES

M-87203, M-87206

Some tests reported here may have been developed and performance characteristics determined by specifically cleared or approved by the U.S. Food and Drug Administration."

these tests have not been

Entire report and diagnosis completed by:

-----END OF REPORT-----

Histology Discrepancy		/
Primary Malignancy History		/
Discrepancy Primary Malignancy		/

Source: NCI Genomic Data Commons file 889a9fe3-16fc-4edc-85d4-f3b07ddd57d8 (TCGA-D3-A5GT.D05F07E0-3A81-4D39-83B5-56F8487CB2BC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).